Gene-level copy-number profile of tumor specimen TCGA-91-8499-01A from TCGA case TCGA-91-8499, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.3 years (27,853 days).
Specimen TCGA-91-8499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.dd4ab024-1ad7-4ece-8451-b3592e9d8959.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-8499-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e011a7e-5b47-4d1d-ac1f-369a132256e0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 4,110; copy number 2: 20,942; copy number 3: 23,535; copy number 4: 6,961; copy number 5: 2,149; copy number 6: 683; copy number 7: 792; copy number 8: 226; copy number 9: 139; copy number 10: 111; copy number 11: 58; copy number 14: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-8499-01A-11D-2389-01): tumor purity 0.77, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:188,713,644–190,092,279, 37 genes: AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,395 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:103,961,616–104,037,543, 1 gene, copy number 7: LINC02503.
- chr5:58,198–5,320,304, 111 genes, copy number 10 (broad region; genes not listed).
- chr5:7,226,156–15,266,541, 133 genes, copy number 7–9 (broad region; genes not listed).
- chr5:29,104,880–29,882,945, 9 genes, copy number 7: AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1.
- chr5:43,287,470–45,098,647, 28 genes, copy number 9: HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr8:37,405,439–42,541,926, 127 genes, copy number 11–14 (within-gene range 3–14) (broad region; genes not listed).
- chr8:70,608,577–71,592,025, 9 genes, copy number 8 (within-gene range 6–8): LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2.
- chr8:86,765,935–132,481,095, 633 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:139,096,305–140,635,633, 15 genes, copy number 7 (within-gene range 6–7): AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1.
- chr11:111,245,726–111,512,354, 10 genes, copy number 9 (within-gene range 4–9): C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4.
- chr12:26,905,181–27,446,625, 13 genes, copy number 7 (within-gene range 5–7): INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1.
- chr12:33,374,238–37,576,384, 19 genes, copy number 7: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P.
- chr12:63,055,275–71,927,248, 195 genes, copy number 8–9 (broad region; genes not listed).
- chr14:77,376,689–77,935,014, 17 genes, copy number 8 (within-gene range 5–8): SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA.
- chr14:81,916,231–83,048,640, 8 genes, copy number 7: EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1, AL359238.1, AL162872.1, RNU7-51P.
- chr18:47,390–2,049,510, 46 genes, copy number 7 (within-gene range 4–7): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:67,481,791–68,715,108, 19 genes, copy number 7: AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3.
- chr18:68,721,082–68,754,583, 2 genes, copy number 7: AC040896.1, AC022035.1.

Autosomal genes at a single copy (total copy number 1): 3,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
